Surgical pathology report (de-identified scan), TCGA case TCGA-RD-A8N2, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Peter MacCallum Cancer Center, specimen TCGA-RD-A8N2-01A (Primary Tumor).

[page 1 of 2]
Requested by

Gender

Date of Birth

Consultant

Location

F

REQUEST NO:

Date Requested:

Date Collected:

Date Authorised:

CLINICAL NOTES

Japanese style partial gastrectomy including entire lesser sac. Antral cancer.

MACROSCOPY

Specimen labelled stomach. Received is a gastrectomy specimen including the antrum lesser sac and the portion of greater omentum, 140mm along lesser curvature, 185mm along greater curvature with maximum circumference of mucosal surface 130mm. In the antrum of the specimen is a lesion comprising an ulcerated firm white sessile mass 25mm maximum dimension on mucosal surface and macroscopically seen to extend well into the stomach wall. There is no obvious involvement of overlying serosa. Surrounding mucosa is of macroscopically normal appearance. On the cut surface the lesion has maximum dimension of 50mm. A1 proximal margin of stomach, A2 distal stomach margin, A3 lesion at distal edge, A4, A5 further sections of tumour, A6 - tumour at proximal edge, A7 mucosa from macroscopically normal looking body of stomach, A8 mucosa from normal looking proximal body, A9, A10 single sections of node from greater omentum, A11, A12 single sections of node from lesser omentum, A13 nodes and omentum from proximal pedicle.

DIAGNOSIS

Partial gastrectomy - gastric antral ulcerated diffuse infiltrative poorly differentiated signet ring cell carcinoma with infiltration of the full thickness of muscularis propria. Carcinoma is not seen at serosal surfaces of the stomach. There is no demonstrable lymphovascular or perineural space invasion. Sections from the gastric proximal and distal surgical resection margins are free of tumour. All 6 of 6 greater omental lymph nodes sampled are normal. All 17 of 17 lesser omental lymph nodes sampled are normal. Tissues sampled from the proximal pedicle consist of adipose connective tissue only and are without lymph nodes.

Reported by :
DISEASE Codes

ICD O-3

Adenocarcinoma, diffuse type

Carcinoma, signet ring cell

Site: Gastric antrum

*Pw TSS dx discrepancy
form, TCGA tumor is
adenocarcinoma, diffuse type
(with signet ring).*

HPV Discrepancy	☒	☒

Anatomical Patho

MEDICATION RECORD

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

1/1/17

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Signet ring adenocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Adenocarcinoma - diffuse type.	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form			
3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Signet rings are a histologic characteristic associated only with diffuse type adenocarcinoma	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my Institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Principal Investigator has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file a7999fbe-85d0-40d9-a4c0-d6bca99c2a36 (TCGA-RD-A8N2.90F42537-F387-421B-AF3E-3AC01904E473.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).